Surgical pathology report (de-identified scan), TCGA case TCGA-50-8460, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-50-8460-01A (Primary Tumor).

FINAL DIAGNOSIS:**PART 1: LYMPH NODE, LEVEL 11, BASILAR SEGMENT, BIOPSY –**

ONE (1) BENIGN LYMPH NODE WITH ANTHRACOTIC PIGMENT DEPOSITS, FREE OF TUMOR (0/1).

PART 2: LYMPH NODE, LEVEL 11, MIDDLE LOBE, BIOPSY –

ONE (1) BENIGN LYMPH NODE WITH ANTHRACOTIC PIGMENT DEPOSITS, FREE OF TUMOR (0/1).

PART 3: LUNG, RIGHT UPPER LOBE POSTERIOR SEGMENTECTOMY –

- A. INVASIVE PAPILLARY ADENOCARCINOMA WITH A FEW PSAMMOMA BODIES AND FOCAL LEPIDIC GROWTH, MODERATELY DIFFERENTIATED, PERIPHERAL SUBPLEURAL (2.0 X 2.0 X 1.8 CM.).
- B. NEGATIVE FOR VISCERAL PLEURA INVASION (PLO).
- C. NEGATIVE FOR LYMPHOVASCULAR INVASION.
- D. SURGICAL PARENCHYMAL MARGIN OF RESECTION NEGATIVE FOR TUMOR (TUMOR AT 2.0 CM.).
- E. EMPHYSEMATOUS CHANGES.
- F. AJCC TNM STAGE: pT1a N0.

PART 4: LYMPH NODE, LEVEL 4, BIOPSY –

ONE (1) LYMPH NODE WITH ANTHRACOTIC PIGMENT DEPOSITS, FREE OF TUMOR (0/1).

PART 5: LYMPH NODE LEVEL 10, BIOPSY –

ONE (1) BENIGN LYMPH NODE, FREE OF TUMOR (0/1).

PART 6: LYMPH NODE, LEVEL 7, BIOPSY –

ONE (1) BENIGN LYMPH NODE, FREE OF TUMOR (0/1).

COMMENT:

Special elastic stains performed on slides 3A and 3B with adequate controls are negative for tumor invasion of visceral pleura.

Molecular studies were performed on the previous right upper lobe FNA biopsy [REDACTED] they are EGFR, KRAS and BRAF negative. ALK FISH studies positive.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY LUNG TUMORS**

TUMOR LOCATION:	Right Upper Lobe
LUNG SEGMENT(S) INVOLVED:	Posterior
PROCEDURE:	Segmental
TUMOR SIZE:	Maximum dimension: 2.0 cm Minor dimension: 2.0 cm
TUMOR TYPE:	Invasive adenocarcinoma, Dominant Pattern: Papillary
HISTOLOGIC GRADE:	G2, Moderately differentiated
EXTRAPULMONARY EXTENSION/INVASION OF TUMOR:	None identified (PLO)
ANGIOLYMPHATIC INVASION:	No
TUMOR NECROSIS:	< or = to 50%
SURGICAL MARGIN INVOLVEMENT:	No
SURGICAL MARGIN SITE:	Distance of invasive tumor to closest margin: 20 mm, Parenchymal margin
INFLAMMATORY(DESMOPLASTIC) REACTION:	Mild
N1 LYMPH NODES:	Number of N1 lymph nodes positive: 0 Number of N1 lymph nodes examined: 3
N2 LYMPH NODES:	Number of N2 lymph nodes positive: 0 Number of N2 lymph nodes examined: 2
UNDERLYING DISEASE(S):	Emphysema
T STAGE, PATHOLOGIC:	pT1a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	Not applicable
ANCILLARY STUDIES:	Histochemical stains, FISH studies, Molecular studies

Source: NCI Genomic Data Commons file 7347a417-82f5-473b-830e-307b06c53fc7 (TCGA-50-8460.FC79E8C5-C79B-46D3-AB41-03399A68999A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).